Surgical pathology report (de-identified scan), TCGA case TCGA-AC-A6IX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-AC-A6IX-06A (Metastatic).

[page 1 of 6]
Metastatic LN

Patient: [Redacted]

Referring Physician: [Redacted]

DOB: [Redacted] Age: [Redacted] Gender: F

Ref#: [Redacted]

Hosp#: [Redacted]

Provider Group: [Redacted]

Date of Service: [Redacted] Date Received: [Redacted]

Date Reported: [Redacted]

A copy of this report will be faxed to: [Redacted]

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

1CD-0-3

Carcinoma, infiltrating lobular, nos
8520/3

Site: lymph node, axillary

C77.3

lw
3/5/14

A. -B.) LEFT BREAST, MODIFIED RADICAL MASTECTOMY:

- Multicentric invasive lobular carcinoma, Nottingham grade 2.
- Tumor size: 3.5 cm.
- Smaller tumor nodules: 0.1 to 1.2 cm in diameter.
- Atypical lobular hyperplasia and atypical ductal hyperplasia.
- Metastatic carcinoma in nineteen of twenty-one axillary lymph nodes (19/21).
- Largest metastatic focus: 2.5 cm; extranodal extension present.
- One of the nodes was previously biopsied.
- Mastectomy margins are free of tumor.
- Carcinoma is 1 cm from the deep margin, and at least 1 cm from all other margins.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade (invasive): Invasive lobular carcinoma, Nottingham grade 2.
Primary tumor: pT2(m).
Regional lymph nodes: pN3a.
Distant metastasis: Not applicable.
Pathologic stage: IIIC.
Margin status: Negative.

COMMENT: The main tumor mass is located in the 3-4:00 region of the breast, and grossly measures 3.5 cm in diameter. Adjacent to this nodule is a 1.2 cm secondary nodule. A third 0.5 cm nodule is identified in the lower inner quadrant, and small foci of invasive tumor are located in the subareolar breast tissue. The separately submitted lymph node (specimen B) is positive for metastatic carcinoma, and is included in the total lymph node count above.

Invasive Breast Cancer Tumor Staging Information

AJCC Cancer Staging Handbook, 7th Ed., and CAP Protocol (revised June 2012).
Previous pathology specimens [Redacted]

Case #

Printed:

Page 1

This report continues. (FINAL)

MR No. - [Redacted]
Pathology - Page 1/6

Acct No. [Redacted]

Patient Name - [Redacted]

Page 1 Doc# 1

[page 2 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Case #:

Printed:

Page 2

This report continues. (FINAL)

MR No. -
Pathology - Page 2/6

Acct No.

Patient Name

Page 2 Doc# 1

[page 3 of 6]
Patient:

Case #:

SPECIMEN IDENTIFICATION

Procedure/specimen type:

Laterality:

Lymph node sampling:

Modified radical mastectomy.

Left.

Lymph node dissection.

INVASIVE CARCINOMA TUMOR CHARACTERISTICS

Histologic type:

Tumor site:

Tumor size:

Tumor focality:

Histologic grade (Nottingham Score):

Tubule formation:

Nuclear pleomorphism:

Mitotic rate:

Invasive lobular carcinoma.

Main mass 3-4:00 aspect.

3.5 cm.

Multicentric.

2 of 3.

3 of 3.

2 of 3.

1 of 3.

Lymphovascular invasion:

Macroscopic and microscopic extent of tumor:

Indeterminate.

No skin or chest wall invasion is identified.

DUCTAL CARCINOMA IN SITU (DCIS):

Not identified.

MARGINS

Invasive carcinoma:

† 1 cm from deep margin, at least 1 cm from all other margins.

LYMPH NODES

Total lymph nodes examined

Number of lymph nodes involved

Size of largest metastatic deposit:

Extranodal extension:

21.

19.

2.5 cm.

Present around multiple lymph nodes.

PATHOLOGIC STAGING:

Primary Tumor (pT):

Regional lymph nodes (pN):

Distant metastasis (pM):

AJCC Stage:

pT2(m).

pN3a.

Not applicable.

IIIC.

ANCILLARY STUDIES:

Estrogen receptor:

Progesterone receptor:

HER2:

Ki-67:

98% positive cells, strong intensity.

Less than 1% positive cells, strong intensity.

IHC score 1+.

5% positive cells.

Case #:

Printed:

Page 3

This report continues. (FINAL)

[page 4 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Breast; left
- B. Apical node

Clinical History/Operative Dx:

Left breast cancer

Gross Description:

A. Received fresh labeled "modified radical mastectomy" is a right modified radical mastectomy specimen. The breast measures 16 cm (medial-lateral) x 15 cm (superior-inferior) x 5 cm (anterior-posterior), and weighs 538 g. There is an elliptical portion of tan skin measuring 15 x 8 cm, with nipple and areola present just medial of center. The attached axillary tail measures 10 x 4 x 1.5 cm. The specimen is inked as follows:

Blue - Superior,
Orange - Inferior,
Black - Deep.

The specimen is sliced from medial to lateral in nine slices with slice 1 most medial, slice nine most lateral (including axillary tail). The nipple is in slice #4.

There is a dominant mass in the 3-4:00 aspect of the specimen, approximately 5 cm from the nipple, measuring 3.5 x 3 x 2 cm. This mass is 2 cm from the closest inferior margin, 1 cm from the deep margin, and is at least 4 cm from all other margins. A nodule is appreciated superior-posterior to lesion #1, 1.2 x 0.8 cm, within slabs 4-5.

There is a second ill-defined nodule located approximately 3 cm superior to the largest mass, located in the upper outer quadrant, approximately 2 cm in diameter. A third ill-defined area of nodularity is identified in the upper inner quadrant measuring up to 2.5 cm in diameter, located in slabs 3-4, from

Case #:

Printed:

Page 4

This report continues... (FINAL)

[page 5 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

medial. In the lower inner quadrant, there is a 0.5 cm nodule, at least 1 cm from the nearest margin.

There is ill-defined nodularity in the lower outer quadrant region, apart from the main tumor, and areas of central fibrocystic changes. The axillary tail contains prominent lymph nodes, the largest of which is 2.5 cm in diameter. Portions of tumor and non-tumor breast tissue, and a portion of the suspicious lymph node are submitted for research. Time removed from breast: Time placed in formalin:

Representative sections are submitted according to the following slide key:

- A1) nipple (slab 4),
- A2) medial and lateral extension of skin represented,
- A3) lower outer quadrant,
- A4) lesion #1, lower outer quadrant,
- A5) lesion #1, overlying skin,
- A6) lesion #1, deep margin relationship,
- A7) lesion #1, lower outer quadrant, adjacent inferior superficial surgical margin, slab 6,
- A8) lesion #1, slab 7,
- A9) lower outer quadrant, adjacent to lesion #1, slab 8,
- A10-A11) discrete bilobed nodularity, superior to lesion #1, slabs 4-5, respectively,
- A12) second (#2) ill-defined mass, slab 5,
- A13) second ill-defined mass, slab 6,
- A14) second ill-defined mass, superior edge, slab 7,
- A15) deep surgical margin adjacent to second ill-defined mass,
- A16) superior superficial surgical margin adjacent to second ill-defined mass, slab 6,
- A17) upper outer quadrant, slab 8,
- A18) third nodule, upper inner quadrant, adjacent to second ill-defined mass, slab 4, adjacent deep margin separate piece,
- A19) upper inner quadrant, third nodular area, slab 3,
- A20) upper inner quadrant, deep surgical margin, adjacent to third nodular area suspicion, slab 3,
- A21) upper inner quadrant, superficial surgical margin adjacent to third nodular area of suspicion, slab 3,
- A22) upper inner quadrant, adjacent to third nodular area. slab 1,
- A23) lower inner quadrant, slab 2,
- A24) central breast - subareolar area, slab 4,
- A25) discrete nodule, lower inner quadrant,
- A26-A27) largest lymph node,
- A28) four lymph nodes,
- A29) five lymph nodes,
- A30) two lymph nodes bisected, one marked orange,
- A31) two lymph nodes bisected, one marked orange,
- A32) larger and smaller lymph node, each bisected, one marked orange,
- A33) single lymph node bisected,
- A34) single lymph node bisected,
- A35) single lymph node bisected

B. Part B designated apical node. Received is a single pink-gray, dense gray lymph node candidate, 1.3 x 0.7 x 0.5 cm. The node is submitted in its entirety, bisected in B1.

Case #:

Printed:

Page 5

This report continues... (FINAL)

[page 6 of 6]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

This is a metastatic lymph node.

Reviewed (Initials) W 3/5/14 Date Reviewed: 01/13/13		

Case #:

Printed:

Page 6

END OF REPORT (FINAL)

Source: NCI Genomic Data Commons file 80e0b54a-40c3-4357-87a2-62aea043e4f8 (TCGA-AC-A6IX.A92859DA-41AD-4CF9-86AF-E4073E6276ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).